Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KN, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KN-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology

Page 1 of 3

Unit No

REPORT Tel:

Clinical Consultant & Location

Sex

This Copy For:

SPECIMEN

LEFT ENUCLEATED EYE, PROGNOSTIC

CLINICAL DETAILS

Choroidal melanoma.

Tumour size: 13.7 x 15 (4.4)mm.

MACROSCOPIC DESCRIPTION

A fresh, intact left globe.

Dimensions: Axial 22.5mm, Horizontal 24mm, Vertical 24mm

Cornea: Horizontal 11.5mm, Vertical 11mm

Optic nerve

Length 3.5mm, Diameter 4mm

Pupil: regular

Angle: normal

On trans-illumination, a large shadow approximately 13.5mm in diameter is seen extending between the optic nerve and just anterior to the equator.

Plane of section: oblique

Intraocular description:

On opening, a solitary dome shaped choroidal pigmented mass is seen - 1mm of the optic disc.

Tumour size

LBD 15mm, Height 4.7mm

MICROSCOPY

Sections show a variably pigmented choroidal melanoma of mixed cell type in which the epithelioid cells amount up to 60%. Focal peripheral area of the tumour shows clear cell changes / balloon type of cells. Tumour cells express Melan-A and HSP 27 (score 2).

ICD-O-3
Melanoma, epithelioid, spindle
cell mixed 8770/3
Site: @Choroid C693
QD 1/17/14

Reported:

Pathologist:

Electronically Verified:

[page 2 of 3]
Department of Pathology

Page 2 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

The number of mitosis is small, approximately 2/40 high power fields. The microvasculature of the melanoma is prominent, and closed loops are present in the planes of sections. The lymphocytic infiltrate within the tumour is minimal. Scattered macrophages are present. Tumour necrosis is not seen. Bruch's membrane appears breached in the sections examined. There is minimal tumour extension into the sclera. No tumour is seen in sections of optic nerve or vortex veins examined. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is shallow. The iris shows no significant abnormality but the ciliary body appears atrophic with hyalinisation of ciliary processes. The lens shows subcapsular degenerative changes. Retina overlying the tumour is slightly atrophic.

DIAGNOSIS

Left eye, enucleation: Choroidal melanoma of mixed cell type.

SUMMARY

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed
CT LOOPS	2= Closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	2/40 HPF
SER10 FREQUENCY	2/40 HPF
DIFFUSE MELANOMA	No
SPREAD	2= Intra-scleral

Reported:

Pathologist:

Electronically Verified:

[page 3 of 3]
Department of Pathology

Page 3 of 3

HISTOPATHOLOGY REPORT Tel:

Surname	Lab No	Clinical Consultant & Location
Forename(s)	DOB/Age	Sex
Unit No	Request Date	

This Copy For:

CLEARANCE 2= Adequate

HSP-27 POSITIVITY 2= 21-70%

LARGE DIAMETER 15 mm
THICKNESS 4.7 mm

COMMENT

MOLECULAR DIAGNOSTICS

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from , which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

loss of chromosome 1p,
monosomy 3,
partial losses of chromosome 6
and gains in chromosome 8q.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist:

Electronically Verified:

Primary Tumour Site Discrepancy		✓
HivAA Discrepancy		✓

Source: NCI Genomic Data Commons file e2e9cab4-6242-4a65-a1f1-612199403938 (TCGA-VD-A8KN.78FF7875-29D1-4636-89A2-5D19ACACA019.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).